Gene-level copy-number profile of tumor specimen TCGA-09-0369-01A from TCGA case TCGA-09-0369, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.7 years (20,705 days).
Specimen TCGA-09-0369-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.0ae9f973-4f93-48f0-a214-35d671d46fef.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-09-0369-10C (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (sample pair TCGA-09-0369-01A|TCGA-09-0369-10B); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/26423687-0af0-4d74-8d25-73bd628fb81a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 3,022; copy number 2: 26,644; copy number 3: 21,911; copy number 4: 6,275; copy number 5: 1,191; copy number 6: 675; copy number 8: 14; copy number 9: 34; copy number 10: 28; copy number 17: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-09-0369-01A-01D-0356-01): tumor purity 0.9, ploidy 2.64, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:110,083,870–110,116,022, 1 gene (within-gene range 0–3): MALL.
- chr2:110,122,311–110,245,420, 3 genes: NPHP1, ACTR1AP1, MTLN.
- chr2:133,333,829–133,333,930, 1 gene: RNU6-579P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,952 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:57,048,350–60,100,200, 23 genes, copy number 5: EIF2S2P7, AC132153.1, AC068276.1, AC073875.1, ACTG1P22, VRK2, AC068193.1, FANCL, AC007250.1, EIF3FP3, LINC01795, LINC01122, AC007238.1, AC007092.1, LINC01793, AC007100.1, AC007179.2, AC007179.1, AC007179.3, RNU6-508P, RNA5SP94, AC007100.2, AC007132.1.
- chr3:165,186,720–198,222,513, 631 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr4:54,440,502–56,033,361, 35 genes, copy number 5: AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, AC110611.2, CEP135.
- chr4:56,097,390–56,097,504, 1 gene, copy number 5: RNA5SP161.
- chr7:139,448,740–141,480,380, 40 genes, copy number 6: RNU6-911P, KLRG2, AC005531.1, CLEC2L, ERHP1, HIPK2, TBXAS1, PARP12, KDM7A, Y_RNA, KDM7A-DT, RNU6-797P, RNU1-58P, AC005377.1, PPP1R2P6, SLC37A3, RNA5SP247, RNA5SP248, RAB19, AC069335.1, MKRN1, DENND2A, Y_RNA, AC006452.1, RN7SL771P, ADCK2, NDUFB2, NDUFB2-AS1, BRAF, RNU6-85P, AC006006.1, CCT4P1, MRPS33, RNU4-74P, TMEM178B, AC006362.1, NDUFB10P2, AC005692.3, AC005692.1, AC005692.2.
- chr7:141,652,381–145,270,384, 205 genes, copy number 6–17 (broad region; genes not listed).
- chr8:150,584–40,353,133, 862 genes, copy number 5 (broad region; genes not listed).
- chr18:30,954,820–31,986,087, 32 genes, copy number 6: AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4.
- chr19:57,240,632–58,605,223, 123 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 982. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
